Gene-level copy-number profile of tumor specimen TCGA-D7-A4YU-01A from TCGA case TCGA-D7-A4YU, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 73.3 years (26,781 days).
Specimen TCGA-D7-A4YU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.0c83fe0f-5a0f-4c54-8d0a-2b72fe09a3f5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-A4YU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9a90d1f0-a15f-4bb5-9b1e-98463f0f5259

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 48; copy number 1: 16,131; copy number 2: 37,640; copy number 3: 5,269; copy number 5: 677; copy number 17: 40; copy number 18: 4; copy number 27: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-A4YU-01A-21D-A253-01): tumor purity 0.33, ploidy 3.44, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 48 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,732,636, 5 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.
- chr9:9,442,060–9,442,380, 1 gene: RN7SL5P.
- chr21:19,593,841–23,709,345, 42 genes: RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1, LINC01683, LINC02573, RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1, LINC00320, PPIAP1, NCAM2, AP001136.1, AP001117.1, AF241725.1, LINC00317, LINC01425, AP000472.1, LINC01687, LINC00308, AP000705.2, AP000705.1, RNU4-45P, AP000561.1, MAPK6P2, AP000959.1, AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1, RNU2-55P, D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1, AP000961.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 732 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:126,556,323–127,419,050, 1 gene, copy number 17 (within-gene range 2–17): PCAT1.
- chr8:126,766,196–130,443,674, 50 genes, copy number 17–27 (within-gene range 2–27): AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1.
- chr8:131,904,093–132,111,159, 4 genes, copy number 18 (within-gene range 2–18): EFR3A, OC90, AC100868.1, HHLA1.
- chr10:44,712–38,783,108, 675 genes, copy number 5 (broad region; genes not listed).
- chr20:15,021,553–15,022,958, 2 genes, copy number 5: RNU6-1159P, RNU6-115P.

Autosomal genes at a single copy (total copy number 1): 13,744. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
